Somatic mutation profile of tumor specimen PCProject_0319_T1_WES (aliquot PCProject_0319_T1_WES_1) from CMI case PCProject_0319, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.1 years (24,499 days).
Specimen PCProject_0319_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9b38843-9cac-4e71-9c3c-16fc7140c677.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0319_SALIVA (Saliva), aliquot PCProject_0319_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbd73885-5c9f-4f99-808b-9a17f181f6fb

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Splice Site 2, Frame Shift Del 1, 5'Flank 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1425+2T>A p.X475_splice (on ENST00000521381 / NM_181523.3; = p.X205_splice on NM_181504.4) | Splice Site (SNP) | VAF 6/64 reads (9%) | hotspot (GDC flag); catalogued as rs1554051075, CS165034, COSV57135132, COSV57139824; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 8/84 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARHGAP31 | c.2449C>G p.L817V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs541827684; called by muse, mutect2, varscan2
- LCE1A | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as rs377226562; called by muse, mutect2, varscan2
- OLR1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs986422401, COSV58871028; called by muse, mutect2, varscan2
- SVEP1 | c.6792T>G p.C2264W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52838632; called by muse, mutect2
- TDRD12 | c.2860C>A p.Q954K (on ENST00000444215; = p.Q959K on NM_001366102.1) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.251); catalogued as rs1357027425; called by muse, mutect2, varscan2
- UBE2C | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1386174145; called by muse, mutect2
- ARHGEF3 | c.375+2T>C p.X125_splice | Splice Site (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- C1orf56 | c.623C>G p.P208R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEFSEC | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NLRP13 | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- RLF | c.4933del p.S1645Vfs*11 | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | called by mutect2, pindel, varscan2
- SGIP1 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPANXN4 | c.46C>G p.P16A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- SPANXN4 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ARHGAP35 | c.366G>A p.A122= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1367696580; called by muse, mutect2, varscan2
- ARHGEF7 | c.2397C>T p.I799= (on ENST00000375741 / NM_001113511.2; = p.I778= on NM_145735.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, varscan2
- HMCN1 | c.2784A>T p.S928= | Silent (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- PTPRQ | c.3015A>C p.S1005= (on ENST00000616559; = p.S963= on NM_001145026.2) | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2
- TBX5 | c.126G>A p.P42= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100090527; called by muse, mutect2
- PPDPFL | c.*5C>A | 3'UTR (SNP) | VAF 16/128 reads (13%) | catalogued as rs1359505756; called by muse, mutect2, varscan2
- RHOBTB3 | chr5:95730879 G>A | 5'Flank (SNP) | VAF 7/62 reads (11%) | catalogued as rs1456596308; called by muse, mutect2
- ZNF295-AS1 | n.205T>C | RNA (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- ZNF77 | c.-10_-9del | 5'UTR (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
